Surgical pathology report (de-identified scan), TCGA case TCGA-06-1084, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1084-01A (Primary Tumor).

[page 1 of 2]
06-1084

Surgical Pathology Report

CLINICAL HISTORY

Left frontal brain tumor.

OPERATIVE DIAGNOSES

Spitfire3

Operation/Specimen: A: Brain, left frontal tumor, biopsy

B: Brain, left frontal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, left frontal tumor, excision: Gliosarcoma (WHO Grade IV) (see comment).

COMMENT

This is an unusual glial tumor that fits the general pattern of a gliosarcoma. Because of the prominent epithelioid pattern it could also be classified as an "epithelioid glioblastoma" which is within the spectrum of gliosarcomas.

The Ki-67 labeling index is 30 to 40% and the tumor is diffusely p53 immunopositive. MGMT promoter methylation testing will be reported in an addendum.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on tissue block

ST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed

[page 2 of 2]
[REDACTED]

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

LAB COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

Brain, biopsy: Malignant neoplasm, defer further to permanents. Frozen section and smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

B.

SPECIMEN: Left frontal brain tumor.

FIXATIVE: Formalin.

GENERAL: Received is a 3.6 x 1.7 x 1.2 cm aggregate irregular pink-tan hemorrhagic soft to rubbery tissue fragments.

SECTIONS: The specimen is submitted entirely in 3 cassettes.

[REDACTED]

MICROSCOPIC DESCRIPTION

Sections of specimens A. and B. show a pleomorphic epithelioid neoplasm demonstrating prominent nucleoli. In some areas the tumor cells are arranged in a nested pattern. Occasional gland-like structures apparently containing secretory material are noted. Most of the tumor is composed of large epithelioid cells although some areas are composed of smaller cells with scant cytoplasm. Frequent mitotic figures, occasional apoptotic bodies and large areas of necrosis are present. Microvascular proliferation and pseudopalisading necrosis are not prominent features. Immunohistochemical stains show that the tumor is GFAP, vimentin and S100 positive. HMB-45 and pan-keratin are negative. Occasional cells show diffuse EMA cytoplasmic positivity. The reticulin pattern is somewhat biphasic as are the GFAP and vimentin staining patterns. The tumor is diffusely p53 positive and the Ki-67 labeling index is 30 to 40%.

ICD-9(s):

191.9 191.9

[REDACTED]

Histo Data

[REDACTED]

Source: NCI Genomic Data Commons file b00a35fd-931f-4cab-8976-7451670d1579 (TCGA-06-1084.85FA99BB-28F3-4529-9263-ACE020EA8634.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).